Somatic mutation profile of tumor specimen 1105230 (aliquot 7316UP-302-1105230) from CPTAC case C204057, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Parietal lobe; Tumor grade: G4.
Specimen 1105230: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f303af4e-ef03-45f9-bfb7-74c9a4063183.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105284 (Blood Derived Normal), aliquot 7316UP-302-1105284; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90dc3880-7eae-437a-bf76-be01311b7f33

The open-access MAF lists 66 somatic variants for this specimen: 40 protein-altering or splice-affecting, 18 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 18, Intron 4, 3'UTR 3, Nonsense Mutation 3, Frame Shift Del 2, In Frame Del 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.1529A>T p.Q510L | Missense Mutation (SNP) | VAF 67/471 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM043070, CM052358, COSV61008620; called by muse, mutect2, varscan2
- AHDC1 | c.1945G>C p.A649P | Missense Mutation (SNP) | VAF 41/192 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.083); catalogued as CD1515401; called by muse, mutect2, varscan2
- ARMCX2 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs782307127, COSV100168205; called by muse, mutect2, varscan2
- CBLL2 | c.974G>T p.G325V | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV100081584; called by muse, mutect2, varscan2
- CDH9 | c.799C>T p.R267* | Nonsense Mutation (SNP) | VAF 30/116 reads (26%) | catalogued as rs779923057, COSV50275360, COSV50343795; called by muse, mutect2
- CDK5R2 | c.653G>C p.R218P | Missense Mutation (SNP) | VAF 15/519 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56935841; called by muse, mutect2
- CR1 | c.2606T>C p.I869T | Missense Mutation (SNP) | VAF 53/424 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV65456805; called by muse, mutect2, varscan2
- DGKQ | c.1988G>T p.R663L | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as rs752503518, COSV53281525; called by muse, mutect2, varscan2
- DSG2 | c.2084C>T p.T695M | Missense Mutation (SNP) | VAF 65/335 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as rs200137091; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ENPP2 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.821); catalogued as rs377608124; called by muse, mutect2, varscan2
- FLG | c.10204C>T p.R3402W | Missense Mutation (SNP) | VAF 125/565 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.087); catalogued as rs141655789; called by muse, mutect2, varscan2
- GPR31 | c.4C>G p.P2A | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV64761869; called by muse, mutect2
- HECW1 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 53/281 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1335374674, COSV67836832, COSV67837728; called by muse, mutect2, varscan2
- IQCF1 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 106/462 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as rs752889161, COSV58823372; called by muse, mutect2, varscan2
- KCNB2 | c.478C>T p.R160* | Nonsense Mutation (SNP) | VAF 25/152 reads (16%) | catalogued as rs748825911, COSV73048736; called by muse, mutect2, varscan2
- KCNQ5 | c.1603C>T p.R535W | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763071667; called by muse, mutect2, varscan2
- LILRA4 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs749644963, COSV52492535; called by muse, mutect2, varscan2
- OR52B6 | c.563G>T p.C188F | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756504887; called by muse, mutect2, varscan2
- PPP1R3F | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 96/473 reads (20%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs782455380; called by muse, mutect2, varscan2
- PRKAG2 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 95/500 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as rs200392688; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RBBP8NL | c.1345C>T p.R449W | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780896548; called by muse, mutect2, varscan2
- RELB | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs775189147, COSV55508233; called by muse, mutect2
- SLC6A8 | c.1318C>T p.R440C | Missense Mutation (SNP) | VAF 68/314 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); catalogued as rs782326194; called by muse, mutect2, varscan2
- SSPN | c.616G>A p.G206S | Missense Mutation (SNP) | VAF 67/302 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs745893300; called by muse, mutect2, varscan2
- ANOS1 | c.1355-2A>G p.X452_splice | Splice Site (SNP) | VAF 57/336 reads (17%) | called by muse, mutect2, varscan2
- CRYBG2 | c.1757del p.P586Lfs*15 | Frame Shift Del (DEL) | VAF 44/249 reads (18%) | called by mutect2, pindel, varscan2
- ELF3 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- HCFC1 | c.5141C>T p.T1714I | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KCNQ3 | c.1082A>G p.E361G | Missense Mutation (SNP) | VAF 68/359 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- KIFC3 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- LILRB2 | c.763G>T p.V255F | Missense Mutation (SNP) | VAF 48/352 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); called by muse, varscan2
- MAP7D2 | c.1607A>G p.E536G | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NF1 | c.7924_7925del p.Y2642Lfs*17 (on ENST00000358273 / NM_001042492.3; = p.Y2621Lfs*17 on NM_000267.3) | Frame Shift Del (DEL) | VAF 52/283 reads (18%) | called by mutect2, pindel, varscan2
- NRK | c.2620G>T p.G874* | Nonsense Mutation (SNP) | VAF 11/63 reads (17%) | called by muse, mutect2, varscan2
- OR5M1 | c.820A>C p.T274P | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.317); called by muse, mutect2
- PITPNM1 | c.2827C>T p.P943S | Missense Mutation (SNP) | VAF 51/221 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RPS3A | c.619C>G p.L207V | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- SLITRK6 | c.1772C>A p.T591K | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- UIMC1 | c.58_60del p.K20del | In Frame Del (DEL) | VAF 26/186 reads (14%) | called by pindel, varscan2
- ZNF195 | c.319G>T p.G107C | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- CDH7 | c.1965C>T p.D655= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as rs116347805, COSV59889152; called by muse, mutect2
- CYP4F3 | c.315C>G p.T105= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as COSV99658828; called by muse, mutect2, varscan2
- DCAF12L2 | c.306G>A p.A102= | Silent (SNP) | VAF 55/300 reads (18%) | catalogued as COSV63582487, COSV63584428; called by muse, mutect2, varscan2
- EXPH5 | c.4192T>C p.L1398= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs376155497; called by muse, mutect2, varscan2
- FERMT1 | c.423G>A p.P141= | Silent (SNP) | VAF 24/117 reads (21%) | catalogued as rs41308076; called by muse, mutect2, varscan2
- FLNC | c.2271C>T p.N757= | Silent (SNP) | VAF 27/122 reads (22%) | catalogued as rs779105468; called by muse, mutect2, varscan2
- IGKV1D-42 | c.81C>A p.T27= | Silent (SNP) | VAF 30/200 reads (15%) | called by muse, mutect2, varscan2
- PALM2AKAP2 | c.246T>C p.G82= (on ENST00000259318 / NM_001136562.3; = p.G313= on NM_007203.5) | Silent (SNP) | VAF 26/136 reads (19%) | called by muse, mutect2, varscan2
- PCDH7 | c.1164C>A p.R388= | Silent (SNP) | VAF 67/264 reads (25%) | catalogued as COSV62342343; called by muse, mutect2, varscan2
- PCDHB15 | c.1893C>T p.S631= | Silent (SNP) | VAF 154/763 reads (20%) | called by muse, mutect2, varscan2
- PCLO | c.10737A>G p.Q3579= | Silent (SNP) | VAF 45/220 reads (20%) | called by muse, mutect2, varscan2
- PDZD4 | c.1893C>T p.D631= | Silent (SNP) | VAF 44/212 reads (21%) | catalogued as COSV51251460; called by muse, mutect2, varscan2
- PHLDB2 | c.525G>A p.S175= | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as rs376563651, COSV101208401, COSV67312695; called by muse, mutect2, varscan2
- PIK3AP1 | c.1432C>A p.R478= | Silent (SNP) | VAF 36/146 reads (25%) | catalogued as COSV59531507, COSV59531568; called by muse, mutect2, varscan2
- SCNN1B | c.285C>T p.V95= | Silent (SNP) | VAF 40/208 reads (19%) | called by muse, mutect2, varscan2
- SIRPA | c.696C>T p.H232= | Silent (SNP) | VAF 71/492 reads (14%) | catalogued as rs769493586, COSV61537567; called by muse, mutect2, varscan2
- SLC17A9 | c.1095G>A p.P365= | Silent (SNP) | VAF 23/122 reads (19%) | catalogued as rs756409472, COSV64848272; called by muse, mutect2, varscan2
- TRIM6 | c.279A>G p.K93= | Silent (SNP) | VAF 51/276 reads (18%) | catalogued as rs139606995; called by muse, mutect2, varscan2
- APPL2 | c.416-10T>C | Intron (SNP) | VAF 46/176 reads (26%) | catalogued as rs369697149; called by muse, mutect2, varscan2
- CCL4L2 | c.191+88G>A | Intron (SNP) | VAF 26/128 reads (20%) | catalogued as rs755259101; called by muse, mutect2, varscan2
- COBL | c.1096+2108C>T | Intron (SNP) | VAF 26/197 reads (13%) | catalogued as rs540915260; called by muse, mutect2, varscan2
- F5 | c.*39G>C | 3'UTR (SNP) | VAF 38/163 reads (23%) | called by muse, mutect2, varscan2
- LILRB5 | c.1630-109G>C | Intron (SNP) | VAF 43/384 reads (11%) | called by muse, mutect2, varscan2
- MIR508 | n.35G>T | RNA (SNP) | VAF 32/154 reads (21%) | called by muse, mutect2, varscan2
- MRPL54 | c.*34G>A | 3'UTR (SNP) | VAF 52/243 reads (21%) | catalogued as rs766782435; called by muse, mutect2, varscan2
- TDRD6 | c.*3G>A | 3'UTR (SNP) | VAF 23/119 reads (19%) | catalogued as rs749611205, COSV51267111; called by muse, mutect2, varscan2
